Somatic mutation profile of tumor specimen 1312a0e0-5025-433e-9670-0595bb (aliquot 1312a0e0-5025-433e-9670-0595bb_D6) from CPTAC case 05CO035, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 1312a0e0-5025-433e-9670-0595bb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df887106-389f-47d6-a51b-29057b7ed8cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c69ba610-1bdb-41b6-8369-a83016 (Blood Derived Normal), aliquot c69ba610-1bdb-41b6-8369-a83016_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46110805-9788-4c33-8beb-ff72da84b200

The open-access MAF lists 262 somatic variants for this specimen: 177 protein-altering or splice-affecting, 53 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 53, Intron 21, Nonsense Mutation 6, Splice Site 6, RNA 5, Frame Shift Ins 4, 5'UTR 3, 3'UTR 3, Frame Shift Del 3, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.2883C>T p.G961= | Silent (SNP) | VAF 148/441 reads (34%) | catalogued as rs1298655924, COSV57052813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCAT2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749866079, CM159648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 81/245 reads (33%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 199/361 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65317510; called by muse, mutect2, varscan2
- ACSL1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775407611; called by muse, mutect2, varscan2
- ADAMTS13 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 186/488 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1554790334; called by muse, mutect2, varscan2
- ADAMTS20 | c.3233C>A p.A1078D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV67126759; called by muse, mutect2, varscan2
- AKR1C1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs570906796; called by muse, mutect2
- APC | c.3958del p.V1320* | Frame Shift Del (DEL) | VAF 208/578 reads (36%) | catalogued as COSV57329357, COSV57361042; called by mutect2, pindel, varscan2
- ARID1A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV61373914; called by muse, mutect2, varscan2
- ASTN1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760958680, COSV56070701; called by muse, mutect2, varscan2
- BICC1 | c.238-1G>T p.X80_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV65863130; called by muse, mutect2, varscan2
- CAD | c.5561G>A p.R1854Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.186); catalogued as rs753204449, COSV53024592; called by muse, mutect2, varscan2
- CBLL2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV60369238; called by muse, mutect2, varscan2
- CBX6 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53321440, COSV99328053; called by muse, mutect2, varscan2
- CCDC127 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57257588; called by muse, mutect2, varscan2
- CCDC17 | c.174G>A p.A58= | Splice Region (SNP) | VAF 31/94 reads (33%) | catalogued as rs1337807779; called by muse, mutect2, varscan2
- CCDC25 | c.115T>C p.W39R | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1337145190, COSV100738367; called by muse, mutect2, varscan2
- CCND1 | c.855C>A p.C285* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99919854; called by muse, mutect2, varscan2
- CHL1 | c.1123C>A p.P375T (on ENST00000397491 / NM_001253387.1; = p.P391T on NM_006614.4) | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56609271; called by muse, mutect2
- CLDN6 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1455379665, COSV58511108; called by muse, mutect2, varscan2
- CNBP | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV69654357; called by muse, mutect2
- DISP3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs1196600137; called by muse, mutect2, varscan2
- DLL3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 70/493 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs141671275; called by muse, mutect2, varscan2
- DMRTB1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1444843178, COSV65113050; called by muse, mutect2
- DOK6 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs893415202, COSV101234285, COSV66932088; called by muse, mutect2, varscan2
- DYSF | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 164/486 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs762862531; called by muse, mutect2, varscan2
- FAF1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as rs762629521; called by muse, mutect2, varscan2
- FAM9A | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.198); catalogued as rs764416645, COSV101121332; called by muse, mutect2, varscan2
- FER1L6 | c.4177C>T p.R1393W | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376465322; called by muse, mutect2, varscan2
- HFM1 | c.4163dup p.N1388Kfs*8 | Frame Shift Ins (INS) | VAF 15/21 reads (71%) | catalogued as rs759278255, COSV99646600; called by mutect2, varscan2
- HMCN2 | c.4102G>A p.A1368T | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs531001000, COSV101338672; called by muse, mutect2, varscan2
- IGKV1-12 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 154/872 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288969140; called by muse, mutect2, varscan2
- IQSEC3 | c.1015C>T p.R339C (on ENST00000538872 / NM_001170738.2; = p.R36C on NM_015232.1) | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58280238; called by muse, mutect2, varscan2
- KLHDC1 | c.709A>T p.R237W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as rs757879867; called by mutect2, varscan2
- KLRC2 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1006808993; called by muse, mutect2, varscan2
- MAGEL2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious, low confidence (0); catalogued as rs758752541; called by muse, mutect2, varscan2
- MAP3K11 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58421977; called by muse, mutect2, varscan2
- MAP7D2 | c.766G>C p.V256L | Missense Mutation (SNP) | VAF 139/193 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65530520; called by muse, mutect2, varscan2
- MED13 | c.3593A>G p.N1198S | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.753); catalogued as rs764465757; called by muse, mutect2, varscan2
- MED24 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs764139973; called by muse, mutect2, varscan2
- MICAL1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs192304860; called by muse, mutect2, varscan2
- MPDZ | c.4930G>A p.V1644I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764834512; called by muse, mutect2, varscan2
- MRPL39 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs766266905, COSV56260689; called by muse, mutect2
- NBEA | c.4245G>A p.T1415= | Splice Region (SNP) | VAF 18/134 reads (13%) | catalogued as COSV59766796; called by muse, mutect2, varscan2
- NID1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs202192927; called by muse, mutect2, varscan2
- OR2AJ1 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100561459; called by muse, mutect2, varscan2
- OR4D5 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746149575, COSV58306026; called by muse, mutect2, varscan2
- PAX1 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 126/578 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs758893794; called by muse, mutect2, varscan2
- PCDHA8 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 23/603 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs781800527, COSV65327217; called by muse, mutect2
- PCDHB2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 167/505 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.251); catalogued as COSV50564080; called by muse, mutect2, varscan2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2, varscan2
- PHTF2 | c.1075C>T p.R359W (on ENST00000248550 / NM_001366089.1; = p.R321W on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1028389825, COSV50330348; called by muse, mutect2, varscan2
- POLQ | c.5594C>T p.S1865F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.486); catalogued as COSV51747004; called by muse, mutect2, varscan2
- PPARGC1B | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143433281; called by muse, mutect2, varscan2
- PPP1R12B | c.2791G>C p.V931L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780257688; called by muse, mutect2, varscan2
- PPP1R3A | c.2984A>G p.Q995R | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV99493008; called by muse, mutect2
- PREPL | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as rs1339995644; called by muse, mutect2, varscan2
- PROKR2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 365/1116 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146729363, COSV99449940; called by muse, mutect2, varscan2
- QSER1 | c.349C>G p.R117G (on ENST00000399302; = p.R246G on NM_001076786.3) | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67900907; called by muse, mutect2, varscan2
- RECQL | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776939203, COSV53711985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPE65 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 96/346 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs370076628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9L | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs569239575, COSV59079569; called by muse, mutect2, varscan2
- SGCG | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs774245371, COSV104374639, COSV54565704; called by muse, mutect2, varscan2
- SMG8 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56284915; called by muse, mutect2, varscan2
- SOWAHD | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 117/150 reads (78%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs575793972; called by muse, mutect2, varscan2
- SPATA2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 148/404 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs750170146, COSV56866348; called by muse, mutect2, varscan2
- ST3GAL1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 33/166 reads (20%) | PolyPhen benign (0.012); catalogued as rs772036212; called by muse, mutect2, varscan2
- TAF1L | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535964605, COSV54258565; called by muse, mutect2, varscan2
- TBC1D9 | c.1114A>G p.I372V | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.241); catalogued as rs927674021; called by muse, mutect2
- TLL1 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263487, COSV50268157; called by muse, mutect2, varscan2
- TPSD1 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs200938484; called by muse, mutect2, varscan2
- TRPC6 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs759107251; called by muse, mutect2, varscan2
- TTC29 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 105/289 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as rs902361836; called by muse, mutect2, varscan2
- TULP1 | c.961T>G p.Y321D | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs794726991, CM1310211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNIP | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100997345; called by muse, mutect2, varscan2
- USP20 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs551465675, COSV59616875; called by muse, mutect2, varscan2
- ZFAT | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1438595068, COSV64738216; called by muse, mutect2, varscan2
- ZFHX4 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50764690; called by muse, mutect2, varscan2
- ZNF23 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 119/329 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1296756682; called by muse, mutect2, varscan2
- ZNF425 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770372995; called by muse, mutect2, varscan2
- ZNF585A | c.397G>A p.A133T (on ENST00000292841 / NM_001288800.2; = p.A78T on NM_152655.3) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs533790578, COSV53062969, COSV53067130; called by muse, mutect2, varscan2
- ACVR2B | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 131/388 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.1451_1454del p.R484Tfs*12 | Frame Shift Del (DEL) | VAF 146/507 reads (29%) | called by mutect2, pindel, varscan2
- ADGRF2 | c.1125A>T p.K375N (on ENST00000296862 / NM_001368115.2; = p.K307N on NM_153839.7) | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADGRL3 | c.3395A>G p.N1132S (on ENST00000506720 / NM_001322402.2; = p.N1064S on NM_015236.6) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ADGRL4 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ADGRV1 | c.2521A>C p.T841P | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADPRM | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL1 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ALG8 | c.1580G>T p.*527Lext*? | Nonstop Mutation (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- ANKDD1A | c.689A>T p.H230L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP8B4 | c.2849T>A p.F950Y | Missense Mutation (SNP) | VAF 102/175 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP8B4 | c.2812C>A p.P938T | Missense Mutation (SNP) | VAF 92/162 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, varscan2
- BPNT1 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2
- C10orf71 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2
- CACNA2D3 | c.765A>T p.K255N | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CACNA2D3 | c.3188A>C p.N1063T | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CAPN13 | c.803T>G p.I268S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CDH22 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CDS2 | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CEP44 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP43 | c.1686A>T p.Q562H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CFAP47 | c.1379A>C p.E460A | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CFHR3 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CHD7 | c.5462T>A p.V1821D | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- CILP2 | c.3328G>A p.G1110R | Missense Mutation (SNP) | VAF 97/137 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- CLHC1 | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.2096T>A p.V699D | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRNN | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CSMD1 | c.4500G>T p.E1500D (on ENST00000520002; = p.E1499D on NM_033225.6) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP4F22 | c.939G>C p.R313S | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DACH2 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- DCDC1 | c.4102G>C p.E1368Q (on ENST00000597505 / NM_001367979.1; = p.E475Q on NM_020869.3) | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- DIP2B | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.103); called by muse, mutect2
- DMD | c.5424A>T p.K1808N | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); called by muse, mutect2
- DNAJB14 | c.637+1G>T p.X213_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- EBF3 | c.285A>T p.K95N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2
- EHD3 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EOLA1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 218/294 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ERF | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F12 | c.1824G>T p.W608C | Missense Mutation (SNP) | VAF 145/395 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FCRL5 | c.341T>A p.F114Y | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GIPR | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GOLGA2 | c.1715T>G p.L572R | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- GORAB | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR179 | c.947A>G p.Y316C (on ENST00000621958; = p.Y315C on NM_001004334.4) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HDGFL1 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HIVEP3 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- HMCN1 | c.15773G>C p.C5258S | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRNR | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HSD17B2 | c.1080T>A p.D360E | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2
- INSRR | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 150/419 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF20B | c.2773_2774insC p.K925Tfs*7 (on ENST00000371728 / NM_001284259.2; = p.K885Tfs*7 on NM_016195.4) | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- KRT6B | c.816+1G>T p.X272_splice | Splice Site (SNP) | VAF 114/378 reads (30%) | called by muse, mutect2, varscan2
- LATS1 | c.2269C>G p.L757V | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCT | c.4464+1G>T p.X1488_splice | Splice Site (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- MAGEB1 | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAST4 | c.6931G>A p.G2311R (on ENST00000403625 / NM_001164664.2; = p.G2122R on NM_015183.3) | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- METAP2 | c.772+2T>C p.X258_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- MTSS2 | c.654del p.T219Pfs*13 | Frame Shift Del (DEL) | VAF 48/164 reads (29%) | called by mutect2, pindel, varscan2
- MUC17 | c.5581A>T p.T1861S | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBAS | c.4482_4486dup p.Q1496Pfs*15 | Frame Shift Ins (INS) | VAF 77/247 reads (31%) | called by mutect2, pindel, varscan2
- NGEF | c.1087T>A p.Y363N | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NLRP8 | c.1429G>C p.A477P | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NMBR | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NUDT3 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OLFM3 | c.845G>T p.R282M (on ENST00000338858 / NM_001288821.1; = p.R262M on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- OR4Q2 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- OR8K5 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- OR9Q1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARD3B | c.2870A>G p.N957S (on ENST00000406610 / NM_001302769.2; = p.N888S on NM_057177.7) | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PARP1 | c.2720A>G p.Y907C | Missense Mutation (SNP) | VAF 50/385 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBX1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCGF2 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PCLO | c.14299G>C p.E4767Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR3GL | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- POSTN | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PRDM9 | c.632T>A p.F211Y | Missense Mutation (SNP) | VAF 140/409 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PSMD1 | c.2569G>C p.D857H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RARS1 | c.961A>T p.K321* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- SAP30 | c.541-1G>C p.X181_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- SENP7 | c.2546A>G p.D849G | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SETD5 | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SETDB2 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.161); called by muse, mutect2
- SH3GL3 | c.81_82dup p.K28Ifs*3 | Frame Shift Ins (INS) | VAF 39/81 reads (48%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.2973_2990dup p.S996_W997insCKTSFS | In Frame Ins (INS) | VAF 64/216 reads (30%) | called by mutect2, varscan2
- STXBP6 | c.218C>A p.S73* | Nonsense Mutation (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 169/487 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TENM2 | c.2997C>G p.N999K (on ENST00000518659 / NM_001122679.2; = p.N767K on NM_001080428.3) | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TRBV3-1 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- UBXN10 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XPO4 | c.2683G>T p.G895W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZFYVE26 | c.5753A>T p.E1918V | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ZNF33A | c.370C>G p.P124A (on ENST00000458705 / NM_006974.3; = p.P125A on NM_006954.2) | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2
- ZNF773 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ADGRA3 | c.3327C>T p.S1109= | Silent (SNP) | VAF 101/298 reads (34%) | catalogued as rs781447096, COSV99293576; called by muse, mutect2, varscan2
- BAIAP3 | c.3184C>T p.L1062= | Silent (SNP) | VAF 27/209 reads (13%) | called by muse, mutect2, varscan2
- CACHD1 | c.2685C>T p.D895= | Silent (SNP) | VAF 14/167 reads (8%) | catalogued as rs763001657; called by muse, mutect2
- CAMK2D | c.708A>G p.P236= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- CCP110 | c.513G>A p.P171= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs748288173; called by muse, mutect2, varscan2
- CCR8 | c.711C>T p.I237= | Silent (SNP) | VAF 20/305 reads (7%) | called by muse, mutect2
- CES2 | c.150C>T p.G50= | Silent (SNP) | VAF 116/298 reads (39%) | catalogued as rs368628668; called by muse, mutect2, varscan2
- CHRNA7 | c.1143C>T p.N381= | Silent (SNP) | VAF 29/541 reads (5%) | catalogued as rs542404300, COSV60967848; called by muse, mutect2
- COL3A1 | c.2298T>C p.P766= | Silent (SNP) | VAF 80/229 reads (35%) | called by muse, mutect2, varscan2
- CSMD2 | c.6486G>A p.T2162= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as rs753174399, COSV53889587, COSV53944433; called by muse, mutect2, varscan2
- DCAF12L2 | c.1161C>A p.A387= | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- DGKK | c.1527C>T p.L509= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- DNAH14 | c.10011T>C p.A3337= (on ENST00000445597; = p.A4345= on NM_001367479.1) | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- DOCK4 | c.4728G>T p.L1576= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- DSCAML1 | c.6078A>T p.T2026= (on ENST00000321322; = p.T1966= on NM_020693.4) | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- EGR4 | c.564C>T p.S188= (on ENST00000545030; = p.S85= on NM_001965.4) | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- EYA3 | c.1299G>T p.V433= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- FA2H | c.177C>T p.S59= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs1436602238; called by muse, mutect2, varscan2
- FAM131C | c.492C>T p.S164= | Silent (SNP) | VAF 85/210 reads (40%) | catalogued as rs368938930; called by muse, mutect2, varscan2
- FAT4 | c.819G>A p.A273= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs748050828, COSV67890420; called by muse, mutect2, varscan2
- FCRL5 | c.945G>A p.L315= | Silent (SNP) | VAF 95/315 reads (30%) | called by muse, mutect2, varscan2
- FRY | c.3528C>T p.G1176= | Silent (SNP) | VAF 287/472 reads (61%) | called by muse, mutect2, varscan2
- GDPGP1 | c.348G>A p.R116= | Silent (SNP) | VAF 115/222 reads (52%) | called by muse, mutect2, varscan2
- HFE | c.414C>T p.Y138= | Silent (SNP) | VAF 23/389 reads (6%) | catalogued as rs780563614, CM091840, COSV100352751; called by muse, mutect2
- IL21R | c.183G>A p.E61= | Silent (SNP) | VAF 132/362 reads (36%) | called by muse, mutect2, varscan2
- ISM1 | c.888C>T p.S296= | Silent (SNP) | VAF 54/361 reads (15%) | called by muse, mutect2, varscan2
- ITGAD | c.3183C>T p.V1061= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs143897954; called by muse, mutect2, varscan2
- KCNS2 | c.666C>T p.G222= | Silent (SNP) | VAF 35/754 reads (5%) | catalogued as rs759268206, COSV54637800, COSV54640130; called by muse, mutect2
- KLF4 | c.708C>T p.S236= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs772714572, COSV65929427; called by muse, mutect2, varscan2
- KRT79 | c.1179G>A p.A393= | Silent (SNP) | VAF 111/272 reads (41%) | catalogued as rs573197551, COSV57939073; called by muse, mutect2, varscan2
- LINGO2 | c.1434C>T p.S478= | Silent (SNP) | VAF 71/238 reads (30%) | catalogued as rs757019380, COSV58056428, COSV58064695; called by muse, mutect2, varscan2
- MICAL3 | c.537C>A p.V179= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- MYOF | c.1905C>T p.A635= | Silent (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1572C>T p.H524= | Silent (SNP) | VAF 274/738 reads (37%) | catalogued as rs1554164570, COSV56536366; called by muse, mutect2, varscan2
- PCDHGA2 | c.717G>A p.A239= | Silent (SNP) | VAF 110/281 reads (39%) | catalogued as rs778153551, COSV53926549; called by muse, mutect2, varscan2
- PCDHGA3 | c.747G>C p.V249= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- PCDHGB2 | c.1932C>T p.V644= | Silent (SNP) | VAF 196/566 reads (35%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3049A>C p.R1017= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV65745677; called by muse, mutect2, varscan2
- PRDM2 | c.1731T>C p.N577= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as rs1557647680; called by muse, mutect2, varscan2
- PTPRZ1 | c.276C>T p.N92= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- REPIN1 | c.564G>A p.Q188= | Silent (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- RXFP3 | c.111G>A p.T37= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV100347146, COSV57504436; called by muse, mutect2, varscan2
- SERPINA5 | c.822G>A p.K274= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- SLC30A8 | c.897T>G p.S299= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- SLC6A1 | c.114G>A p.A38= | Silent (SNP) | VAF 94/286 reads (33%) | catalogued as rs139224269; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPAG17 | c.5145G>C p.R1715= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- SPSB4 | c.162C>T p.H54= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as rs1342954232; called by muse, mutect2, varscan2
- TENM3 | c.7881C>T p.R2627= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- TMEM221 | c.654C>A p.T218= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- USP36 | c.468T>G p.A156= | Silent (SNP) | VAF 78/197 reads (40%) | called by muse, mutect2, varscan2
- VWA1 | c.594G>C p.L198= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- VWF | c.2806C>T p.L936= | Silent (SNP) | VAF 137/416 reads (33%) | called by muse, mutect2, varscan2
- ABCA10 | c.35-937_35-911del | Intron (DEL) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- AKR1B1P6 | n.127T>G | RNA (SNP) | VAF 102/191 reads (53%) | called by muse, mutect2
- AKR1C1 | c.570+741A>T | Intron (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- AL008638.2 | n.239G>A | RNA (SNP) | VAF 95/254 reads (37%) | catalogued as rs1480665222; called by muse, mutect2, varscan2
- C1QL2 | c.-3G>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- CARS2 | c.393+3520G>T | Intron (SNP) | VAF 53/102 reads (52%) | called by muse, mutect2, varscan2
- CFH | c.2957-10C>T | Intron (SNP) | VAF 52/167 reads (31%) | catalogued as COSV66411248; called by muse, mutect2, varscan2
- CNTN2 | c.1110+23C>T | Intron (SNP) | VAF 56/138 reads (41%) | catalogued as rs575930607; called by muse, mutect2, varscan2
- COL6A5 | c.7820-102A>G | Intron (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- DEFB110 | c.-16del | 5'UTR (DEL) | VAF 11/34 reads (32%) | catalogued as rs34202705; called by mutect2, pindel, varscan2
- DST | c.4296+4283C>G | Intron (SNP) | VAF 55/375 reads (15%) | catalogued as COSV55024500; called by muse, mutect2, varscan2
- FBXO4 | c.*3C>G | 3'UTR (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99889346; called by muse, mutect2, varscan2
- ITPRIPL1 | c.11-21C>G | Intron (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- LINC01565 | n.1259C>T | RNA (SNP) | VAF 87/236 reads (37%) | called by muse, mutect2, varscan2
- LRBA | c.6363+8261G>T | Intron (SNP) | VAF 8/111 reads (7%) | catalogued as rs963191478; called by muse, mutect2
- MAP9 | c.1822-2295C>A | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MMAB | c.*335G>A | 3'UTR (SNP) | VAF 86/254 reads (34%) | catalogued as rs745373257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1H3 | c.43+202C>A | Intron (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- RAB3IP | c.1278+38T>C | Intron (SNP) | VAF 100/238 reads (42%) | called by muse, mutect2, varscan2
- RB1 | c.-54C>T | 5'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SNORD116-20 | n.51G>A | RNA (SNP) | VAF 87/184 reads (47%) | called by muse, mutect2, varscan2
- SOCS2 | c.-213-883C>G | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- STAR | c.65-50A>G | Intron (SNP) | VAF 65/220 reads (30%) | called by muse, mutect2, varscan2
- TCF4 | c.-20-16A>C | Intron (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- TECTA | c.4105+36C>A | Intron (SNP) | VAF 87/273 reads (32%) | called by muse, mutect2, varscan2
- TRPA1 | c.1644+51T>G | Intron (SNP) | VAF 20/280 reads (7%) | catalogued as COSV51559281; called by muse, mutect2
- TTC21B | c.262+23T>G | Intron (SNP) | VAF 56/140 reads (40%) | catalogued as COSV54629359; called by muse, mutect2, varscan2
- UBA1 | c.1939-144T>C | Intron (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+3146G>T | Intron (SNP) | VAF 47/163 reads (29%) | called by muse, mutect2, varscan2
- ZNF711 | c.*20G>T | 3'UTR (SNP) | VAF 33/106 reads (31%) | catalogued as rs756138833; called by muse, mutect2, varscan2
- ZNF733P | n.499C>G | RNA (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- ZNF783 | c.802+3301C>T | Intron (SNP) | VAF 40/92 reads (43%) | catalogued as rs573291734; called by muse, mutect2, varscan2
